Gene-level copy-number profile of tumor specimen TCGA-D3-A3CC-06A from TCGA case TCGA-D3-A3CC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 71.7 years (26,173 days).
Specimen TCGA-D3-A3CC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.9faf0d44-3fd7-4084-b611-247e276938d2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A3CC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5be1e473-3ecd-4e1a-8c88-1ff744fa0682

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 983; copy number 2: 9,038; copy number 3: 20,798; copy number 4: 26,380; copy number 5: 1,377; copy number 6: 166; copy number 7: 68; copy number 8: 3; copy number 9: 21; copy number 10: 265; copy number 11: 325; copy number 12: 139; copy number 13: 6; copy number 14: 6; copy number 15: 4; copy number 17: 98; copy number 18: 45; copy number 22: 47; copy number 26: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A3CC-06A-11D-A192-01): tumor purity 0.63, ploidy 3.42, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,500,337–88,049,823, 17 genes: AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 980 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,252,006–1,350,786, 5 genes, copy number 9: AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7.
- chr5:4,012,708–4,147,429, 3 genes, copy number 11: AC025773.1, AC025187.1, LINC02063.
- chr5:4,967,764–5,490,220, 15 genes, copy number 11: AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1.
- chr5:6,532,891–6,757,044, 6 genes, copy number 10 (within-gene range 3–10): AC027334.1, LINC01018, NSUN2, SRD5A1, LINC02102, TENT4A.
- chr5:8,659,764–8,980,659, 9 genes, copy number 10: AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199, AC091895.1.
- chr5:10,504,996–12,804,363, 19 genes, copy number 11: LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1, CTNND2, RNU6-429P, RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1.
- chr5:20,830,166–23,528,093, 23 genes, copy number 11: AC138938.1, AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1.
- chr5:23,951,348–24,178,263, 1 gene, copy number 11 (within-gene range 3–11): C5orf17.
- chr5:23,994,502–28,287,807, 43 genes, copy number 11: Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103.
- chr5:30,545,177–30,693,984, 1 gene, copy number 12 (within-gene range 10–12): AC099517.1.
- chr5:31,053,565–31,066,132, 2 genes, copy number 10: RPL19P11, AC026421.1.
- chr5:31,639,131–32,110,932, 1 gene, copy number 11 (within-gene range 3–11): PDZD2.
- chr5:31,820,564–34,158,767, 48 genes, copy number 10–11 (within-gene range 3–11): RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, AC008766.1, NPR3, AC025459.1, AC010343.3, LINC02120, AC034223.1, AC034223.2, AC010343.2, AC010343.1, LINC02160, AC025472.1, AC034231.1, TARS1, TOMM40P3, AC034232.1, ADAMTS12, RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1.
- chr5:36,666,214–37,966,964, 26 genes, copy number 10: AC008957.1, AC008957.3, AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1.
- chr5:38,197,432–44,658,569, 109 genes, copy number 10 (broad region; genes not listed).
- chr5:45,035,199–52,080,987, 31 genes, copy number 11–22: AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1, EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118.
- chr5:53,413,504–53,414,260, 1 gene, copy number 10: AC108114.1.
- chr7:38,256,337–38,335,514, 14 genes, copy number 12: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7.
- chr12:66,767–991,190, 25 genes, copy number 11: IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1.
- chr12:1,151,810–1,153,059, 1 gene, copy number 11: HTR1DP1.
- chr12:5,948,877–8,242,948, 139 genes, copy number 11–17 (within-gene range 11–29) (broad region; genes not listed).
- chr12:8,822,621–9,733,299, 44 genes, copy number 11 (within-gene range 4–11): A2ML1, AC006581.2, PHC1, M6PR, KLRG1, AC006581.1, HNRNPA1P34, VDAC2P2, LINC00612, A2M-AS1, A2M, KRT17P8, BTG1P1, PZP, TPT1P12, A2MP1, MIR1244-3, PTMAP4, LINC00987, AC010175.1, AC009533.1, SNORA75, AC009533.2, AC009533.3, LINC02367, AC009533.4, AC141557.1, AC141557.2, DDX12P, SNORA75, AC092821.3, AC092821.1, AC092821.2, KLRB1, RNU6-700P, GOT2P3, AC010186.4, AC010186.1, AC010186.2, AC010186.3, CLEC2D, NPM1P7, LINC02390, CLECL1.
- chr12:10,226,058–10,777,446, 20 genes, copy number 12 (within-gene range 4–12): KLRD1, LINC02617, LINC02598, KLRK1-AS1, KLRK1, KLRC4-KLRK1, KLRC4, AC068775.1, KLRC3, KLRC2, KLRC1, EIF2S3B, SLC25A39P2, LINC02446, KLRA1P, MAGOHB, STYK1, YBX3, LINC02366, HSPE1P12.
- chr12:11,265,924–11,501,041, 5 genes, copy number 11 (within-gene range 4–11): PRB3, PRB4, PRB1, PRB2, AC078950.1.
- chr12:14,169,746–15,602,175, 34 genes, copy number 12–17: AC092470.1, AC135001.1, AC092112.1, MRPS18CP4, RNU6-491P, GNAI2P1, RPL30P11, ATF7IP, PLBD1, AC008114.1, RN7SKP134, PLBD1-AS1, GUCY2C, AC010168.1, AC010168.2, H4-16, H2AJ, WBP11, C12orf60, SMCO3, AC007655.2, ART4, AC007655.1, MGP, ERP27, ARHGDIB, PDE6H, LINC01489, RERG, RERG-IT1, RERG-AS1, METTL8P1, PTPRO, AC092183.1.
- chr12:16,989,126–17,167,790, 6 genes, copy number 13: SKP1P2, EEF1A1P16, AC092793.1, RNU6-837P, AC092110.1, RPL7P40.
- chr12:18,242,961–18,648,416, 4 genes, copy number 10 (within-gene range 4–10): PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1.
- chr12:19,404,045–21,176,895, 23 genes, copy number 11–18 (within-gene range 4–18): AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1.
- chr12:22,409,237–22,618,868, 2 genes, copy number 12 (within-gene range 4–12): AC053513.1, C2CD5.
- chr12:22,573,425–23,251,499, 10 genes, copy number 12: LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1.
- chr12:23,637,973–23,638,487, 1 gene, copy number 12: AC087260.1.
- chr12:26,800,843–28,581,511, 44 genes, copy number 9–17: AC023051.2, INTS13, FGFR1OP2, TM7SF3, AC024896.1, MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2, STK38L, ARNTL2, ARNTL2-AS1, SMCO2, RARS1P1, PPFIBP1, AC087257.1, AC087257.2, AC009509.3, AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3, AC008011.1, PTHLH, AC008011.2, CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1.
- chr12:29,277,955–30,307,611, 15 genes, copy number 12–18: AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1, TMTC1, AC009320.1, RPL21P99, AC023511.3, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356.
- chr12:30,454,919–34,249,958, 98 genes, copy number 11–18 (broad region; genes not listed).
- chr12:56,521,820–60,419,293, 114 genes, copy number 10–26 (within-gene range 5–26) (broad region; genes not listed).
- chr12:68,332,888–68,451,663, 1 gene, copy number 26 (within-gene range 2–26): LINC02384.
- chr12:68,426,331–68,553,882, 4 genes, copy number 26: AC008033.3, AC008033.1, AC008033.2, RPSAP12.
- chr12:68,808,177–69,584,823, 22 genes, copy number 22: MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2.
- chr12:70,239,114–70,637,440, 8 genes, copy number 18 (within-gene range 2–18): AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.
- chr12:71,439,798–71,586,310, 2 genes, copy number 10 (within-gene range 2–10): LGR5, AC090116.1.

Autosomal genes at a single copy (total copy number 1): 316. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
